Somatic mutation profile of tumor specimen HTMCP-03-06-02439-01A (aliquot HTMCP-03-06-02439-01A-01D-10409) from CGCI case HTMCP-03-06-02439, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2.
Specimen HTMCP-03-06-02439-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ebb83a93-1219-45f1-88e2-5984f63b082c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02439-10A (Blood Derived Normal), aliquot HTMCP-03-06-02439-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3947b71e-86af-405e-aa8f-e1469323729c

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, RNA 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 10/106 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2
- ADAMTS5 | c.2056G>A p.D686N | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs151329117; called by muse, mutect2, varscan2
- C6orf132 | c.2755C>T p.R919W | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1276467013; called by muse, mutect2, varscan2
- ERICH3 | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as COSV100443183; called by muse, mutect2
- M1AP | c.843G>C p.L281F | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.702); catalogued as COSV99304609; called by muse, mutect2
- RGPD4 | c.3961G>A p.E1321K | Missense Mutation (SNP) | VAF 25/532 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.341); catalogued as rs1026687276; called by muse, mutect2
- TMC5 | c.2468C>T p.P823L (on ENST00000396229 / NM_001105248.1; = p.P577L on NM_024780.5) | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs141281985; called by muse, mutect2, varscan2
- WDR81 | c.2267G>A p.R756Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1457395294; called by muse, mutect2
- AKAP3 | c.1231G>A p.G411R | Missense Mutation (SNP) | VAF 31/394 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.813); called by muse, mutect2
- BTAF1 | c.4227C>G p.I1409M | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLG | c.6152C>T p.S2051L | Missense Mutation (SNP) | VAF 21/565 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- NEB | c.2416-1G>A p.X806_splice | Splice Site (SNP) | VAF 8/105 reads (8%) | called by muse, mutect2
- PDS5B | c.1970C>T p.S657L | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTN | c.66509C>A p.P22170Q (on ENST00000591111; = p.P14746Q on NM_003319.4) | Missense Mutation (SNP) | VAF 13/188 reads (7%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- TTN | c.62027C>T p.T20676I (on ENST00000591111; = p.T13252I on NM_003319.4) | Missense Mutation (SNP) | VAF 12/293 reads (4%) | PolyPhen probably damaging (0.998); called by muse, mutect2
- UNC13C | c.5397C>A p.N1799K | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- USP34 | c.6568G>A p.E2190K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- AL592490.1 | c.2703C>A p.I901= | Silent (SNP) | VAF 15/429 reads (3%) | catalogued as COSV101308248; called by muse, mutect2
- KIF20B | c.514C>T p.L172= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs769831424, COSV53306611; called by muse, mutect2
- LMOD3 | c.951C>T p.I317= | Silent (SNP) | VAF 33/314 reads (11%) | catalogued as rs761586160; called by muse, mutect2, varscan2
- PYGB | c.636C>T p.D212= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs199880670; called by muse, mutect2, varscan2
- TTN | c.50631G>A p.K16877= (on ENST00000591111; = p.K9453= on NM_003319.4) | Silent (SNP) | VAF 10/222 reads (5%) | catalogued as rs1053568163; called by muse, mutect2
- CDC42BPA | c.4791+5186G>A | Intron (SNP) | VAF 19/120 reads (16%) | called by muse, mutect2, varscan2
- LINC01719 | n.531C>A | RNA (SNP) | VAF 11/290 reads (4%) | called by muse, mutect2
